Gene-level copy-number profile of tumor specimen TCGA-DK-A3IS-01A from TCGA case TCGA-DK-A3IS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 68.7 years (25,098 days).
Specimen TCGA-DK-A3IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.42739a98-2621-477b-bc4f-1ea32fc065b3.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 420 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d5d50c9-bbf3-4afc-a11e-3e9da10ef665

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 405; copy number 1: 85; copy number 2: 9,016; copy number 3: 20,876; copy number 4: 26,615; copy number 5: 1,139; copy number 6: 1,372; copy number 7: 26; copy number 8: 2; copy number 9: 206; copy number 11: 342; copy number 13: 9; copy number 14: 32; copy number 17: 63; copy number 18: 1; copy number 21: 8; copy number 24: 3; copy number 30: 1; copy number 41: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IS-01A-21D-A219-01): tumor purity 0.9, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,029,594, 56 genes (within-gene range 0–2): AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 516 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,353,696–172,666,876, 400 genes, copy number 9–17 (broad region; genes not listed).
- chr1:176,017,277–176,018,760, 1 gene, copy number 18: AL590723.1.
- chr1:198,450,666–201,112,451, 46 genes, copy number 11 (within-gene range 6–11): AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S.
- chr4:499,210–689,271, 9 genes, copy number 13: PIGG, TMEM271, AC116565.1, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3.
- chr4:1,574,062–1,808,872, 8 genes, copy number 14: AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3.
- chr4:2,269,582–2,418,651, 1 gene, copy number 30 (within-gene range 6–30): ZFYVE28.
- chr4:3,503,612–3,590,711, 3 genes, copy number 24: LRPAP1, AL590235.1, LINC00955.
- chr4:6,320,578–6,884,170, 14 genes, copy number 17 (within-gene range 3–17): PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232.
- chr4:8,269,754–8,619,761, 10 genes, copy number 21–41: HTRA3, LINC02517, AC104825.1, ACOX3, RNA5SP152, TRMT44, AC105345.2, AC105345.1, GPR78, CPZ.
- chr4:9,692,495–10,295,579, 24 genes, copy number 14: FAM86MP, ALG1L3P, Metazoa_SRP, AC098976.1, OR7E35P, SLC2A9, DRD5, RNA5SP154, AC108199.1, SLC2A9-AS1, AC005674.1, WDR1, MIR3138, RNA5SP155, AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.

Autosomal genes at a single copy (total copy number 1): 85. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
